CCDI case PBCEUP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7c36a57d-7d2c-48b8-8af4-5d4d058bfd2c

Demographics
Sex at birth: female.

Diagnoses (1)
1. Subependymal giant cell astrocytoma: ICD-O-3 morphology code: 9384/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (448 days).

Biospecimens (3 samples)
- Sample 0DQ7WI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
